Somatic mutation profile of tumor specimen TCGA-CF-A9FM-01A (aliquot TCGA-CF-A9FM-01A-11D-A38G-08) from TCGA case TCGA-CF-A9FM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage I; Tumor grade: High Grade; Age at diagnosis: 50.5 years (18,445 days).
Specimen TCGA-CF-A9FM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32985e88-4669-4640-9ba7-a795343f40f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A9FM-10A (Blood Derived Normal), aliquot TCGA-CF-A9FM-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612ca73f-8018-48fe-a58e-cefb95da5266

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.527dup p.L177Vfs*30 | Frame Shift Ins (INS) | VAF 54/151 reads (36%) | catalogued as rs780123326; called by mutect2, pindel, varscan2
- CSF3 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs772466210, COSV56640196; called by muse, mutect2, varscan2
- CUL7 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs913411323, COSV54814309; called by muse, mutect2, varscan2
- EIF2S1 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56452009; called by muse, mutect2, varscan2
- KIF23 | c.1984A>G p.K662E | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52978234; called by muse, mutect2, varscan2
- KLHDC2 | c.961T>G p.W321G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100027136; called by muse, mutect2, varscan2
- LARP1 | c.1348C>G p.L450V (on ENST00000518297 / NM_033551.3; = p.L373V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60425511; called by muse, mutect2, varscan2
- NELL1 | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs766308588, COSV54248404; called by muse, mutect2, varscan2
- POLE | c.5072G>A p.R1691H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1235110857, COSV57676674; called by muse, mutect2, varscan2
- PPL | c.5204A>G p.Y1735C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52166611; called by muse, mutect2, varscan2
- TRANK1 | c.8413A>G p.I2805V | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs765945772, COSV57144722; called by muse, mutect2, varscan2
- TRIM24 | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV58970066, COSV58970390; called by muse, mutect2, varscan2
- UBE2L3 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641566; called by muse, mutect2, varscan2
- ZMIZ2 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1281158758, COSV99537197; called by muse, mutect2, varscan2
- IREB2 | c.2276del p.G759Efs*13 | Frame Shift Del (DEL) | VAF 100/251 reads (40%) | called by mutect2, pindel, varscan2
- RSPH4A | c.1697dup p.N566Kfs*2 | Frame Shift Ins (INS) | VAF 45/103 reads (44%) | called by mutect2, varscan2
- UGT1A5 | c.521_523del p.R174del | In Frame Del (DEL) | VAF 91/244 reads (37%) | called by mutect2, pindel, varscan2
- DBN1 | c.856C>A p.R286= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs1172088144, COSV52788355, COSV52790979; called by muse, mutect2, varscan2
- DNAH17 | c.7827G>A p.T2609= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs375072159; called by muse, mutect2, varscan2
- MYMK | c.303C>T p.V101= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV60600290; called by muse, mutect2, varscan2
- SIK2 | c.1704G>A p.Q568= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV59251040; called by muse, mutect2, varscan2
- SOGA1 | c.1344G>A p.V448= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1456974346, COSV52914134; called by muse, mutect2, varscan2
- TBC1D9 | c.1320C>T p.S440= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV71307129; called by muse, mutect2, varscan2
- VTCN1 | c.645C>T p.Y215= | Silent (SNP) | VAF 70/150 reads (47%) | catalogued as rs944995526, COSV60222802; called by muse, mutect2, varscan2
- MIR518D | n.65C>T | RNA (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2
